Somatic mutation profile of tumor specimen TCGA-VQ-A8P5-01A (aliquot TCGA-VQ-A8P5-01A-11D-A397-08) from TCGA case TCGA-VQ-A8P5, project TCGA-STAD (Stomach Adenocarcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Adenocarcinoma, intestinal type; Tissue or organ of origin: Body of stomach; AJCC pathologic stage: Stage IIA; Tumor grade: G3; Age at diagnosis: 67.3 years (24,571 days).
Specimen TCGA-VQ-A8P5-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 9236cb23-a673-4b21-a5e5-919117aed2fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-VQ-A8P5-10A (Blood Derived Normal), aliquot TCGA-VQ-A8P5-10A-01D-A39A-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/37313bd7-2adf-4a22-902a-6d9422fb6998

The open-access MAF lists 219 somatic variants for this specimen: 173 protein-altering or splice-affecting, 43 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 155, Silent 43, Nonsense Mutation 7, Frame Shift Ins 4, Splice Site 3, Intron 3, Frame Shift Del 2, In Frame Ins 1, In Frame Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- PREX2 | c.148T>G p.L50V | Missense Mutation (SNP) | VAF 6/33 reads (18%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen possibly damaging (0.73); catalogued as COSV55750189, COSV55751655, COSV99910567; called by muse, mutect2, varscan2
- SMAD4 | c.403C>T p.R135* | Nonsense Mutation (SNP) | VAF 11/39 reads (28%) | catalogued as rs377767326, CM064283, COSV61684940; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.782+1G>T p.X261_splice | Splice Site (SNP) | VAF 10/21 reads (48%) | hotspot (GDC flag); catalogued as rs1555525429, COSV52665287, COSV52673806, COSV52698978; ClinVar: not provided / likely pathogenic; called by muse, mutect2, varscan2
- ABCA13 | c.2680T>G p.L894V | Missense Mutation (SNP) | VAF 30/171 reads (18%) | SIFT tolerated (0.21); PolyPhen possibly damaging (0.848); catalogued as COSV101329895; called by muse, mutect2, varscan2
- ABCD2 | c.1178G>A p.R393Q | Missense Mutation (SNP) | VAF 31/107 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.928); catalogued as COSV58051835; called by muse, mutect2, varscan2
- AFF2 | c.2603A>C p.K868T | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.979); catalogued as COSV53975964, COSV53982508; called by muse, mutect2, varscan2
- AHNAK | c.15022G>A p.E5008K | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT tolerated (0.16); PolyPhen probably damaging (0.992); catalogued as COSV99945285, COSV99949612, COSV99949835; called by muse, mutect2
- AKAP11 | c.1766C>T p.S589L | Missense Mutation (SNP) | VAF 18/120 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as COSV99213390; called by muse, mutect2, varscan2
- AOC3 | c.2137G>A p.E713K | Missense Mutation (SNP) | VAF 33/146 reads (23%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.774); catalogued as rs774804718, COSV57736069; called by muse, mutect2, varscan2
- ARHGAP22 | c.879A>C p.E293D | Missense Mutation (SNP) | VAF 28/72 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.946); catalogued as COSV99984299; called by muse, mutect2, varscan2
- ARMC3 | c.865C>T p.P289S | Missense Mutation (SNP) | VAF 8/64 reads (13%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.774); catalogued as rs1251243013, COSV99957316; called by muse, mutect2, varscan2
- ARMC4 | c.911A>C p.K304T | Missense Mutation (SNP) | VAF 28/174 reads (16%) | SIFT tolerated (0.43); PolyPhen benign (0.001); catalogued as rs1564573831, COSV53468946, COSV99518489; called by muse, mutect2, varscan2
- ARMC5 | c.916G>A p.A306T | Missense Mutation (SNP) | VAF 7/40 reads (18%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.497); catalogued as rs747989024, COSV99192306; called by muse, mutect2, varscan2
- ATP10B | c.4073T>C p.V1358A | Missense Mutation (SNP) | VAF 28/124 reads (23%) | SIFT tolerated (0.54); PolyPhen benign (0); catalogued as COSV100513941; called by muse, mutect2, varscan2
- ATP23 | c.538A>G p.T180A | Missense Mutation (SNP) | VAF 27/95 reads (28%) | SIFT tolerated (0.25); PolyPhen benign (0.012); catalogued as COSV100274397; called by muse, mutect2, varscan2
- BRINP2 | c.1195C>T p.R399C | Missense Mutation (SNP) | VAF 15/75 reads (20%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.994); catalogued as rs1215171222, COSV64177199; called by muse, mutect2, varscan2
- C1orf194 | c.261C>G p.F87L (on ENST00000369948 / NM_001245025.3; = p.F75L on NM_001122961.2 and 2 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 37/140 reads (26%) | SIFT tolerated (0.73); PolyPhen benign (0.35); catalogued as COSV100885116; called by muse, mutect2, varscan2
- C2 | c.2179G>A p.D727N | Missense Mutation (SNP) | VAF 26/113 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100190573; called by muse, mutect2, varscan2
- CACNA2D3 | c.1526T>G p.L509R | Missense Mutation (SNP) | VAF 21/80 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV99869157; called by muse, mutect2, varscan2
- CASP8AP2 | c.4592C>T p.A1531V | Missense Mutation (SNP) | VAF 6/51 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52746115; called by muse, mutect2
- CCDC113 | c.585_588del p.L196Kfs*11 | Frame Shift Del (DEL) | VAF 10/48 reads (21%) | catalogued as rs757278978; called by pindel, varscan2
- CCDC148 | c.1316G>A p.R439H | Missense Mutation (SNP) | VAF 5/50 reads (10%) | SIFT tolerated (0.12); PolyPhen benign (0.073); catalogued as rs200836240, COSV51757936; called by muse, mutect2, varscan2
- CCDC33 | c.1381C>T p.R461C | Missense Mutation (SNP) | VAF 11/29 reads (38%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.731); catalogued as rs538344642, COSV51503588; called by muse, mutect2, varscan2
- CCDC91 | c.424G>A p.E142K | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT deleterious (0.03); PolyPhen benign (0.048); catalogued as COSV100081074; called by muse, mutect2, varscan2
- CDCA2 | c.1048C>A p.L350I | Missense Mutation (SNP) | VAF 14/59 reads (24%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.689); catalogued as rs766314831, COSV100398715; called by muse, mutect2, varscan2
- CDK12 | c.4066C>T p.R1356* (on ENST00000447079 / NM_016507.4; = p.R1347* on NM_015083.3) | Nonsense Mutation (SNP) | VAF 46/1632 reads (3%) | catalogued as rs900412874, COSV101420297; called by muse, mutect2
- CDR1 | c.85G>A p.E29K | Missense Mutation (SNP) | VAF 37/124 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.964); catalogued as COSV65164792; called by muse, mutect2, varscan2
- CEBPZ | c.787C>A p.L263I | Missense Mutation (SNP) | VAF 16/82 reads (20%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.841); catalogued as COSV99135386; called by mutect2, varscan2
- CHD7 | c.1681C>A p.P561T | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated, low confidence (0.98); PolyPhen benign (0.043); catalogued as rs1231245538, COSV101417956; called by muse, mutect2
- CHRNB4 | c.730G>A p.V244M | Missense Mutation (SNP) | VAF 18/126 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.847); catalogued as rs368785360; called by muse, mutect2, varscan2
- CHST8 | c.877G>A p.A293T | Missense Mutation (SNP) | VAF 21/60 reads (35%) | SIFT tolerated (0.32); PolyPhen possibly damaging (0.541); catalogued as rs747129678, COSV52858942; called by muse, mutect2, varscan2
- CNTRL | c.2078C>T p.S693F | Missense Mutation (SNP) | VAF 12/47 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.897); catalogued as COSV99440882; called by muse, mutect2, varscan2
- COL11A1 | c.2510T>C p.L837P | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV100614690, COSV62175663, COSV62200150; called by muse, mutect2, varscan2
- CSMD3 | c.5253G>C p.W1751C (on ENST00000297405 / NM_001363185.1; = p.W1647C on NM_052900.3) | Missense Mutation (SNP) | VAF 89/133 reads (67%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV99822251; called by muse, mutect2, varscan2
- CSMD3 | c.768T>G p.S256R | Missense Mutation (SNP) | VAF 9/106 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.112); catalogued as COSV52295814; called by muse, mutect2
- CTNNA2 | c.1041C>G p.S347R | Missense Mutation (SNP) | VAF 7/44 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV100781384, COSV63553594, COSV63602385; called by muse, mutect2, varscan2
- CYLC2 | c.71G>T p.S24I | Missense Mutation (SNP) | VAF 9/60 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV66340146; called by muse, mutect2, varscan2
- DEGS2 | c.238G>A p.V80M | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.673); catalogued as rs1010473914, COSV59785056; called by muse, mutect2
- DMD | c.4454T>A p.L1485* | Nonsense Mutation (SNP) | VAF 30/81 reads (37%) | catalogued as COSV100817344; called by muse, mutect2, varscan2
- DNAH9 | c.7925C>T p.A2642V | Missense Mutation (SNP) | VAF 70/145 reads (48%) | SIFT tolerated (0.37); PolyPhen benign (0.005); catalogued as rs750150972, COSV52346119; called by muse, mutect2, varscan2
- DOCK2 | c.3173A>C p.K1058T | Missense Mutation (SNP) | VAF 38/68 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV56963361, COSV56971995; called by muse, mutect2, varscan2
- DSG2 | c.1967C>A p.P656H | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.72); catalogued as rs1288233995, COSV99852672; called by muse, mutect2, varscan2
- DST | c.12658A>G p.K4220E (on ENST00000361203 / NM_001374722.1; = p.K1808E on NM_015548.5) | Missense Mutation (SNP) | VAF 8/26 reads (31%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.92); catalogued as COSV99750102; called by muse, mutect2, varscan2
- EIF3G | c.754G>A p.E252K | Missense Mutation (SNP) | VAF 7/71 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99460664, COSV99461893; called by muse, mutect2, varscan2
- ELAVL2 | c.347G>A p.R116H | Missense Mutation (SNP) | VAF 27/68 reads (40%) | SIFT deleterious (0); PolyPhen benign (0.071); catalogued as COSV56358243; called by muse, mutect2, varscan2
- EPB41L3 | c.1416G>C p.K472N | Missense Mutation (SNP) | VAF 12/61 reads (20%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as COSV100548028; called by muse, mutect2, varscan2
- EXO1 | c.2203A>T p.R735W | Missense Mutation (SNP) | VAF 30/82 reads (37%) | SIFT deleterious (0); PolyPhen possibly damaging (0.533); catalogued as COSV100799585; called by muse, mutect2, varscan2
- FAM153A | c.140A>G p.D47G | Missense Mutation (SNP) | VAF 13/69 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.728); catalogued as COSV100646891; called by muse, mutect2, varscan2
- FANCM | c.5696A>G p.E1899G | Missense Mutation (SNP) | VAF 13/60 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99950303; called by muse, mutect2, varscan2
- FAT4 | c.11291T>G p.L3764R | Missense Mutation (SNP) | VAF 24/83 reads (29%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV58677114, COSV58710494; called by muse, mutect2, varscan2
- FERD3L | c.46T>G p.F16V | Missense Mutation (SNP) | VAF 8/27 reads (30%) | SIFT deleterious (0); PolyPhen benign (0.386); catalogued as COSV51761976, COSV51764624; called by muse, mutect2, varscan2
- FIGNL1 | c.1091G>A p.G364E | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV100794821; called by muse, mutect2, varscan2
- FLG | c.4121G>T p.G1374V | Missense Mutation (SNP) | VAF 101/552 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV100910384, COSV64247384; called by muse, mutect2, varscan2
- FOXL1 | c.181G>T p.A61S | Missense Mutation (SNP) | VAF 12/55 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.759); catalogued as COSV100206070; called by muse, mutect2, varscan2
- FPGT-TNNI3K | c.731T>G p.V244G | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.71); catalogued as COSV58558444, COSV58562185; called by muse, mutect2, varscan2
- FRMPD2 | c.22G>A p.A8T | Missense Mutation (SNP) | VAF 36/187 reads (19%) | SIFT tolerated, low confidence (0.4); PolyPhen benign (0.001); catalogued as rs555394402, COSV100951064; called by muse, mutect2, varscan2
- GABRA6 | c.77A>C p.N26T | Missense Mutation (SNP) | VAF 37/56 reads (66%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.045); catalogued as COSV50890984; called by muse, mutect2, varscan2
- GABRA6 | c.247T>C p.F83L | Missense Mutation (SNP) | VAF 51/99 reads (52%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV99194026; called by muse, mutect2, varscan2
- GANAB | c.1640C>T p.S547F | Missense Mutation (SNP) | VAF 24/89 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV100647770, COSV100647967, COSV60462224; called by muse, mutect2, varscan2
- GBF1 | c.3512G>A p.R1171H (on ENST00000369983 / NM_001377137.1; = p.R1170H on NM_004193.3) | Missense Mutation (SNP) | VAF 24/151 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs367953312; called by muse, mutect2, varscan2
- GP2 | c.659T>C p.V220A (on ENST00000381362 / NM_001007240.3; = p.V217A on NM_001502.4) | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as COSV100221208; called by muse, mutect2
- GPR6 | c.229G>A p.V77M | Missense Mutation (SNP) | VAF 61/148 reads (41%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.922); catalogued as COSV51571261; called by muse, mutect2, varscan2
- HEXB | c.881A>G p.H294R | Missense Mutation (SNP) | VAF 18/96 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV99784037; called by muse, mutect2, varscan2
- HMCN1 | c.3080A>T p.K1027M | Missense Mutation (SNP) | VAF 32/78 reads (41%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.907); catalogued as COSV54889062, COSV99623133, COSV99637782; called by muse, mutect2, varscan2
- IGLC2 | c.286G>A p.V96M | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.175); catalogued as rs752931667; called by muse, mutect2, varscan2
- IKZF3 | c.1214A>G p.H405R | Missense Mutation (SNP) | VAF 97/3306 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.119); catalogued as COSV99499129; called by muse, mutect2
- IL23R | c.1096A>T p.M366L | Missense Mutation (SNP) | VAF 17/60 reads (28%) | SIFT tolerated (0.5); PolyPhen benign (0); catalogued as COSV100724527; called by muse, mutect2, varscan2
- IMPG2 | c.1168C>T p.R390C | Missense Mutation (SNP) | VAF 6/45 reads (13%) | SIFT tolerated (0.17); PolyPhen benign (0.27); catalogued as rs531354781, COSV51972965, COSV51982121; called by muse, mutect2, varscan2
- INVS | c.2957C>T p.P986L | Missense Mutation (SNP) | VAF 5/40 reads (13%) | SIFT tolerated, low confidence (0.86); PolyPhen benign (0); catalogued as rs747292561, COSV99316939; called by muse, mutect2, varscan2
- KCNH5 | c.2530C>A p.P844T | Missense Mutation (SNP) | VAF 31/125 reads (25%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV100525082, COSV100525830; called by muse, mutect2, varscan2
- KCNH5 | c.605C>T p.T202M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.991); catalogued as COSV59752371; called by muse, mutect2, varscan2
- KCNV1 | c.304T>G p.F102V | Missense Mutation (SNP) | VAF 9/23 reads (39%) | SIFT deleterious (0); PolyPhen possibly damaging (0.807); catalogued as COSV99818823; called by muse, mutect2, varscan2
- KDM4D | c.1331T>G p.I444S | Missense Mutation (SNP) | VAF 9/74 reads (12%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0.015); catalogued as COSV100624109; called by muse, mutect2, varscan2
- KLF6 | c.478C>T p.Q160* | Nonsense Mutation (SNP) | VAF 24/109 reads (22%) | catalogued as CM065289, COSV99434878; called by muse, mutect2, varscan2
- KLHL3 | c.1679T>C p.V560A | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT tolerated (0.72); PolyPhen benign (0.003); catalogued as COSV100552824; called by muse, mutect2, varscan2
- KLHL6 | c.983C>T p.T328M | Missense Mutation (SNP) | VAF 40/99 reads (40%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.899); catalogued as rs372412048, COSV58066192; called by muse, mutect2, varscan2
- LANCL2 | c.1210G>A p.G404R | Missense Mutation (SNP) | VAF 6/41 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.719); catalogued as rs184542864, COSV99634351; called by muse, mutect2, varscan2
- LARP6 | c.1345G>A p.G449S | Missense Mutation (SNP) | VAF 13/89 reads (15%) | SIFT tolerated (0.75); PolyPhen benign (0.01); catalogued as rs146941351, COSV100150632; called by muse, mutect2, varscan2
- LDOC1 | c.134G>A p.R45H | Missense Mutation (SNP) | VAF 11/31 reads (35%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV100983122; called by muse, mutect2, varscan2
- LIN28A | c.182G>A p.R61H | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.687); catalogued as COSV99575174; called by muse, mutect2, varscan2
- LMAN1L | c.494C>T p.P165L | Missense Mutation (SNP) | VAF 6/37 reads (16%) | SIFT tolerated (0.69); PolyPhen benign (0); catalogued as rs1567223644, COSV100547519; called by muse, mutect2, varscan2
- LRIT2 | c.817C>T p.R273* | Nonsense Mutation (SNP) | VAF 12/63 reads (19%) | catalogued as rs139197166, COSV100258283; called by muse, mutect2, varscan2
- LRRC27 | c.468_470del p.V157del | In Frame Del (DEL) | VAF 14/92 reads (15%) | catalogued as rs1564829254; called by mutect2, pindel, varscan2
- LRRC4B | c.1093G>A p.V365I | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT tolerated (0.23); PolyPhen benign (0.049); catalogued as COSV65349722; called by muse, mutect2, varscan2
- LRRC6 | c.278T>G p.L93R | Missense Mutation (SNP) | VAF 9/93 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51538141, COSV99137687; called by muse, mutect2
- LTA4H | c.500T>G p.L167R | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99956869; called by muse, mutect2, varscan2
- MAGEA1 | c.208T>G p.F70V | Missense Mutation (SNP) | VAF 75/110 reads (68%) | SIFT tolerated (0.35); PolyPhen benign (0.173); catalogued as COSV63119330; called by muse, mutect2, varscan2
- MAMDC2 | c.1286C>A p.A429E | Missense Mutation (SNP) | VAF 19/131 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.809); catalogued as rs751422402, COSV101015146; called by muse, mutect2, varscan2
- MARK1 | c.614A>G p.N205S | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.992); catalogued as COSV100856994; called by muse, mutect2, varscan2
- MDGA2 | c.2955A>C p.E985D (on ENST00000399232 / NM_001113498.2; = p.E687D on NM_182830.4) | Missense Mutation (SNP) | VAF 19/68 reads (28%) | SIFT tolerated (0.32); PolyPhen probably damaging (0.986); catalogued as COSV100636138; called by muse, mutect2, varscan2
- MICALL1 | c.1439C>T p.P480L | Missense Mutation (SNP) | VAF 10/45 reads (22%) | SIFT deleterious (0); PolyPhen possibly damaging (0.495); catalogued as rs745831607, COSV53242981, COSV99316945; called by muse, mutect2, varscan2
- MPG | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 12/75 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.061); catalogued as rs373341989; called by muse, mutect2, varscan2
- MYOC | c.1343C>A p.T448N | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV99231269; called by muse, mutect2
- NAV1 | c.4480G>A p.V1494M | Missense Mutation (SNP) | VAF 17/85 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.183); catalogued as rs1199461580, COSV55225384; called by muse, mutect2, varscan2
- NCALD | c.209G>A p.R70H | Missense Mutation (SNP) | VAF 40/610 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.615); catalogued as rs772560202, COSV55272801; called by muse, mutect2
- NEIL1 | c.570dup p.F191Lfs*2 | Frame Shift Ins (INS) | VAF 41/80 reads (51%) | catalogued as rs34322656; called by mutect2, varscan2
- NEK9 | c.1718T>A p.I573N | Missense Mutation (SNP) | VAF 21/72 reads (29%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.896); catalogued as COSV53132044; called by muse, mutect2, varscan2
- NFASC | c.1045G>A p.A349T (on ENST00000339876 / NM_001378329.1; = p.A360T on NM_015090.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/74 reads (34%) | SIFT deleterious (0); PolyPhen benign (0.151); catalogued as COSV100362661; called by muse, mutect2, varscan2
- NOL6 | c.442G>A p.V148M | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.941); catalogued as rs763391581, COSV53041298, COSV53044537; called by muse, mutect2
- NOLC1 | c.785G>A p.R262Q | Missense Mutation (SNP) | VAF 12/74 reads (16%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as rs764883022, COSV100893540; called by muse, mutect2, varscan2
- NPHS2 | c.944C>T p.T315I | Missense Mutation (SNP) | VAF 10/51 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.08); catalogued as COSV100858107; called by muse, mutect2, varscan2
- NSD2 | c.208G>A p.A70T | Missense Mutation (SNP) | VAF 17/65 reads (26%) | SIFT tolerated (0.32); PolyPhen benign (0.005); catalogued as rs753748334, COSV100372753; called by muse, mutect2, varscan2
- OR1C1 | c.574G>A p.V192I | Missense Mutation (SNP) | VAF 4/28 reads (14%) | SIFT tolerated (0.13); PolyPhen benign (0.021); catalogued as rs775052824, COSV101376173; called by mutect2, varscan2
- OR2A5 | c.33C>A p.F11L | Missense Mutation (SNP) | VAF 11/79 reads (14%) | SIFT tolerated (0.05); PolyPhen benign (0.399); catalogued as COSV101278644, COSV68738722; called by muse, mutect2, varscan2
- OR4A16 | c.314T>G p.L105R | Missense Mutation (SNP) | VAF 22/195 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.434); catalogued as COSV59043856, COSV59044552; called by muse, mutect2, varscan2
- OR52A5 | c.470T>G p.L157R | Missense Mutation (SNP) | VAF 33/64 reads (52%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); catalogued as COSV100263259, COSV56614108; called by muse, mutect2, varscan2
- OR5F1 | c.14A>T p.N5I | Missense Mutation (SNP) | VAF 17/55 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99558337; called by muse, mutect2, varscan2
- OR5L1 | c.17G>C p.C6S | Missense Mutation (SNP) | VAF 29/177 reads (16%) | SIFT tolerated (0.46); PolyPhen possibly damaging (0.584); catalogued as COSV100449884, COSV61734979; called by muse, mutect2, varscan2
- OR8K5 | c.799T>G p.F267V | Missense Mutation (SNP) | VAF 16/72 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.034); catalogued as COSV100537127; called by muse, mutect2, varscan2
- PCDH15 | c.2273A>C p.N758T | Missense Mutation (SNP) | VAF 7/56 reads (13%) | SIFT tolerated (0.13); PolyPhen probably damaging (0.949); catalogued as COSV100213990, COSV57278399; called by muse, mutect2, varscan2
- PCDHB4 | c.1594G>A p.A532T | Missense Mutation (SNP) | VAF 23/91 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.993); catalogued as COSV52025265; called by muse, mutect2, varscan2
- PCDHGC5 | c.352C>T p.R118C | Missense Mutation (SNP) | VAF 7/45 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as rs747085985, COSV99337414, COSV99343532; called by muse, mutect2, varscan2
- PEAR1 | c.254G>A p.R85H | Missense Mutation (SNP) | VAF 5/24 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs749317928, COSV52772654; called by mutect2, varscan2
- PNLIPRP3 | c.572A>G p.D191G | Missense Mutation (SNP) | VAF 38/94 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1222282011, COSV100982295; called by muse, mutect2, varscan2
- POLQ | c.7389+1G>A p.X2463_splice | Splice Site (SNP) | VAF 12/93 reads (13%) | catalogued as rs1375969800, COSV51756552; called by muse, mutect2
- POLR3A | c.2618G>A p.R873Q | Missense Mutation (SNP) | VAF 6/54 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as CM1411433, COSV100965516; called by muse, mutect2, varscan2
- POT1 | c.1729G>A p.D577N | Missense Mutation (SNP) | VAF 29/114 reads (25%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as rs764901825, COSV100713971; called by muse, mutect2, varscan2
- PRKCB | c.633G>T p.K211N | Missense Mutation (SNP) | VAF 19/126 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.93); catalogued as COSV100331896; called by muse, mutect2, varscan2
- PRSS16 | c.1397T>G p.L466R | Missense Mutation (SNP) | VAF 16/115 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.959); catalogued as COSV100041484; called by muse, mutect2, varscan2
- PTPN13 | c.7277G>A p.G2426E (on ENST00000411767 / NM_080683.3; = p.G2407E on NM_006264.3) | Missense Mutation (SNP) | VAF 4/18 reads (22%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.998); catalogued as rs765352499, COSV100363886; called by mutect2, varscan2
- PTPRC | c.3542C>A p.A1181D | Missense Mutation (SNP) | VAF 13/84 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100722030, COSV61410586; called by muse, mutect2, varscan2
- PTPRM | c.1919T>G p.L640* | Nonsense Mutation (SNP) | VAF 18/83 reads (22%) | catalogued as COSV100154329; called by muse, mutect2, varscan2
- PTPRM | c.2318G>A p.R773Q | Missense Mutation (SNP) | VAF 26/66 reads (39%) | SIFT tolerated (0.52); PolyPhen benign (0.273); catalogued as rs759516477, COSV59862442; called by muse, mutect2, varscan2
- PTPRZ1 | c.6546A>C p.E2182D | Missense Mutation (SNP) | VAF 9/46 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.781); catalogued as COSV66442265; called by muse, mutect2, varscan2
- PUS1 | c.589G>C p.D197H | Missense Mutation (SNP) | VAF 13/48 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.942); catalogued as COSV100435099, COSV59034905; called by muse, mutect2, varscan2
- PZP | c.4300A>C p.S1434R | Missense Mutation (SNP) | VAF 38/121 reads (31%) | SIFT tolerated (0.05); PolyPhen probably damaging (0.949); catalogued as COSV54353742; called by muse, mutect2
- RASGRF2 | c.1022G>A p.R341H | Missense Mutation (SNP) | VAF 53/110 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV99428344; called by muse, mutect2, varscan2
- RIMS1 | c.2134A>C p.S712R | Missense Mutation (SNP) | VAF 29/65 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as COSV53451057; called by muse, mutect2, varscan2
- RNF113A | c.733G>A p.E245K | Missense Mutation (SNP) | VAF 13/100 reads (13%) | SIFT tolerated (0.07); PolyPhen benign (0.08); catalogued as rs1263944876, COSV101006942; called by muse, mutect2, varscan2
- RP1 | c.6442G>C p.E2148Q | Missense Mutation (SNP) | VAF 8/120 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.013); catalogued as COSV99606021; called by muse, mutect2
- SEMG2 | c.1146A>G p.I382M | Missense Mutation (SNP) | VAF 19/72 reads (26%) | SIFT tolerated (0.07); PolyPhen benign (0.043); catalogued as COSV101033926; called by muse, mutect2, varscan2
- SETD3 | c.1102T>A p.F368I | Missense Mutation (SNP) | VAF 15/59 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100074785; called by muse, mutect2, varscan2
- SETDB1 | c.473G>A p.R158K | Missense Mutation (SNP) | VAF 20/41 reads (49%) | SIFT tolerated, low confidence (0.13); PolyPhen benign (0.005); catalogued as COSV99643532; called by muse, mutect2, varscan2
- SNTG2 | c.1114T>A p.L372M | Missense Mutation (SNP) | VAF 4/20 reads (20%) | SIFT tolerated (0.17); PolyPhen possibly damaging (0.694); catalogued as COSV57984512, COSV57995286, COSV58009247; called by muse, mutect2
- SPART | c.1340A>C p.K447T | Missense Mutation (SNP) | VAF 26/132 reads (20%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.936); catalogued as COSV100768530; called by muse, mutect2, varscan2
- SPATA31D1 | c.2123A>C p.E708A | Missense Mutation (SNP) | VAF 14/63 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.395); catalogued as COSV100782418; called by muse, mutect2, varscan2
- SPG11 | c.5650C>T p.R1884C | Missense Mutation (SNP) | VAF 26/159 reads (16%) | SIFT tolerated (0.29); PolyPhen benign (0.003); catalogued as rs752889027, COSV55999142; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SPTBN1 | c.3738C>G p.I1246M | Missense Mutation (SNP) | VAF 11/38 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.982); catalogued as COSV100441591; called by muse, mutect2, varscan2
- SPX | c.16A>G p.S6G | Missense Mutation (SNP) | VAF 42/125 reads (34%) | SIFT tolerated (0.2); PolyPhen benign (0.003); catalogued as COSV57020762, COSV99919500; called by muse, mutect2, varscan2
- SWAP70 | c.964C>T p.R322C | Missense Mutation (SNP) | VAF 5/19 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.333); catalogued as rs369193403; called by muse, varscan2
- TAOK2 | c.2098C>G p.R700G | Missense Mutation (SNP) | VAF 60/132 reads (45%) | SIFT deleterious (0); PolyPhen possibly damaging (0.677); catalogued as rs777936445, COSV54233021, COSV99663698; called by muse, mutect2, varscan2
- TAS2R8 | c.813G>T p.E271D | Missense Mutation (SNP) | VAF 27/97 reads (28%) | SIFT tolerated (0.34); PolyPhen benign (0.223); catalogued as rs1396549631, COSV99553520; called by muse, mutect2, varscan2
- TBP | c.1013C>T p.T338M | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.989); catalogued as rs751047986, COSV57832213; called by muse, mutect2, varscan2
- TCHH | c.4996G>A p.D1666N | Missense Mutation (SNP) | VAF 37/154 reads (24%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.033); catalogued as rs757699851, COSV100914870; called by muse, mutect2, varscan2
- TDO2 | c.1189A>T p.S397C | Missense Mutation (SNP) | VAF 6/81 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV101467828; called by muse, mutect2
- TKTL2 | c.1396G>A p.A466T | Missense Mutation (SNP) | VAF 25/89 reads (28%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.949); catalogued as rs776821649, COSV54917974; called by muse, mutect2, varscan2
- TLR4 | c.583T>G p.L195V (on ENST00000355622 / NM_138554.5; = p.L155V on NM_003266.4) | Missense Mutation (SNP) | VAF 32/81 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.147); catalogued as COSV100790653, COSV100790676, COSV62922341; called by muse, mutect2, varscan2
- TNXB | c.11543T>C p.L3848P (on ENST00000647633; = p.L3601P on NM_019105.8 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.996); catalogued as COSV100925704; called by mutect2, varscan2
- TRPS1 | c.2848A>T p.R950* (on ENST00000220888 / NM_001330599.2; = p.R963* on NM_014112.5 and 1 other RefSeq transcript) | Nonsense Mutation (SNP) | VAF 94/220 reads (43%) | catalogued as COSV99627899; called by muse, mutect2, varscan2
- TWF2 | c.1022G>C p.G341A | Missense Mutation (SNP) | VAF 8/52 reads (15%) | SIFT tolerated (0.06); PolyPhen benign (0.176); catalogued as COSV100564428; called by muse, mutect2, varscan2
- UBA2 | c.520A>G p.T174A | Missense Mutation (SNP) | VAF 124/203 reads (61%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as COSV99875284, COSV99875445; called by muse, mutect2, varscan2
- USP29 | c.434A>C p.K145T | Missense Mutation (SNP) | VAF 71/112 reads (63%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.737); catalogued as COSV99517555; called by muse, mutect2, varscan2
- VCAN | c.1268T>C p.L423S | Missense Mutation (SNP) | VAF 27/58 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99424383; called by muse, mutect2, varscan2
- VCAN | c.4784T>G p.V1595G | Missense Mutation (SNP) | VAF 34/61 reads (56%) | SIFT deleterious (0); PolyPhen benign (0.084); catalogued as COSV99424384; called by muse, mutect2, varscan2
- VPS13B | c.10313C>T p.A3438V | Missense Mutation (SNP) | VAF 16/184 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as rs930006569; called by muse, mutect2
- WDR92 | c.1006C>T p.L336F | Missense Mutation (SNP) | VAF 27/142 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54562786, COSV99718115; called by muse, mutect2, varscan2
- XKR3 | c.246A>C p.Q82H | Missense Mutation (SNP) | VAF 11/69 reads (16%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.961); catalogued as COSV100509100; called by muse, mutect2, varscan2
- YTHDF1 | c.623G>A p.S208N | Missense Mutation (SNP) | VAF 12/39 reads (31%) | SIFT tolerated (0.23); PolyPhen benign (0.003); catalogued as COSV100945537; called by muse, mutect2, varscan2
- ZFAND4 | c.626C>T p.S209F | Missense Mutation (SNP) | VAF 20/141 reads (14%) | SIFT deleterious (0); PolyPhen benign (0.133); catalogued as rs777335661, COSV100762852; called by muse, mutect2, varscan2
- ZNF230 | c.233G>A p.G78D | Missense Mutation (SNP) | VAF 24/57 reads (42%) | SIFT tolerated (0.67); PolyPhen benign (0.007); catalogued as COSV101431875; called by mutect2, varscan2
- ZNF292 | c.1431A>C p.E477D | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.493); catalogued as rs1562180455, COSV100369639; called by muse, mutect2, varscan2
- ZNF665 | c.1411C>T p.H471Y (on ENST00000600412; = p.H536Y on NM_024733.5 and 3 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 139/249 reads (56%) | SIFT deleterious (0); PolyPhen probably damaging (0.95); catalogued as COSV101127870; called by muse, mutect2, varscan2
- ZNF782 | c.557C>G p.S186C | Missense Mutation (SNP) | VAF 30/105 reads (29%) | SIFT tolerated (0.15); PolyPhen benign (0); catalogued as COSV100001075, COSV56655831; called by muse, mutect2, varscan2
- ZNF98 | c.173A>C p.K58T | Missense Mutation (SNP) | VAF 21/89 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.178); catalogued as COSV100757567, COSV63334161; called by muse, mutect2, varscan2
- AHCYL1 | c.1504_1508dup p.H503Qfs*7 | Frame Shift Ins (INS) | VAF 27/131 reads (21%) | called by mutect2, pindel, varscan2
- CKAP4 | c.1601del p.S534Ffs*3 | Frame Shift Del (DEL) | VAF 33/128 reads (26%) | called by mutect2, pindel, varscan2
- CPEB1 | c.1459G>T p.D487Y (on ENST00000617958; = p.D422Y on NM_030594.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 7/46 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.961); called by muse, mutect2, varscan2
- CTNNA2 | c.416_417insGCCTGT p.I139delinsMPV | In Frame Ins (INS) | VAF 10/81 reads (12%) | called by mutect2, pindel
- FBP1 | c.880_881dup p.M295Efs*11 | Frame Shift Ins (INS) | VAF 4/32 reads (13%) | called by mutect2, pindel
- FUBP1 | c.1184-6_1184-2del p.X395_splice | Splice Site (DEL) | VAF 13/60 reads (22%) | called by mutect2, pindel, varscan2
- GTF2I | c.2618A>C p.N873T (on ENST00000573035 / NM_032999.4; = p.N832T on NM_001518.5) | Missense Mutation (SNP) | VAF 10/172 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); called by muse, mutect2
- ITCH | c.177_181dup p.N61Tfs*18 | Frame Shift Ins (INS) | VAF 9/56 reads (16%) | called by mutect2, varscan2
- TPTE | c.1566A>C p.K522N (on ENST00000618007 / NM_199261.4; = p.K504N on NM_199259.4) | Missense Mutation (SNP) | VAF 11/94 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.491); called by muse, mutect2, varscan2
- ALLC | c.387C>T p.S129= | Silent (SNP) | VAF 18/99 reads (18%) | catalogued as rs372636443; called by muse, mutect2, varscan2
- ATP10A | c.3738G>A p.L1246= | Silent (SNP) | VAF 17/76 reads (22%) | catalogued as COSV100790748; called by muse, mutect2, varscan2
- ATRNL1 | c.2649G>A p.A883= | Silent (SNP) | VAF 34/80 reads (43%) | catalogued as rs149670730; called by muse, mutect2, varscan2
- BPIFB4 | c.1596C>A p.S532= | Silent (SNP) | VAF 19/100 reads (19%) | catalogued as rs1179577173, COSV100971397; called by muse, mutect2
- CD2AP | c.1668T>G p.S556= | Silent (SNP) | VAF 22/72 reads (31%) | catalogued as COSV100830265; called by muse, varscan2
- CEP128 | c.2847A>G p.G949= | Silent (SNP) | VAF 12/76 reads (16%) | catalogued as rs781185950, COSV99823413; called by muse, varscan2
- CFAP61 | c.615A>C p.T205= | Silent (SNP) | VAF 28/155 reads (18%) | catalogued as COSV99842975; called by muse, mutect2, varscan2
- CNIH3 | c.375C>T p.A125= | Silent (SNP) | VAF 17/80 reads (21%) | catalogued as rs957414210, COSV99685544; called by muse, mutect2, varscan2
- CNOT2 | c.462G>A p.R154= | Silent (SNP) | VAF 39/126 reads (31%) | catalogued as COSV99972285; called by muse, mutect2, varscan2
- CSMD3 | c.2721C>G p.L907= (on ENST00000297405 / NM_001363185.1; = p.L803= on NM_052900.3) | Silent (SNP) | VAF 76/137 reads (55%) | catalogued as rs145310184; called by muse, mutect2, varscan2
- EIF4E1B | c.237G>T p.R79= | Silent (SNP) | VAF 7/14 reads (50%) | catalogued as COSV100024541; called by muse, mutect2, varscan2
- FAM227B | c.480T>G p.T160= | Silent (SNP) | VAF 22/75 reads (29%) | catalogued as COSV100174325; called by muse, mutect2, varscan2
- GPRC5B | c.198C>T p.G66= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as rs775838103, COSV100314870; called by mutect2, varscan2
- GRID2 | c.33C>T p.S11= | Silent (SNP) | VAF 7/28 reads (25%) | catalogued as rs1398885076, COSV56190887; called by muse, mutect2, varscan2
- IL21R | c.6G>A p.P2= | Silent (SNP) | VAF 7/12 reads (58%) | catalogued as rs1337631595, COSV61970967; called by muse, mutect2, varscan2
- KCNN2 | c.714G>A p.T238= (on ENST00000264773; = p.T450= on NM_021614.4) | Silent (SNP) | VAF 37/89 reads (42%) | catalogued as rs368102188, COSV53282775; called by muse, mutect2, varscan2
- LIPE | c.2808C>T p.G936= | Silent (SNP) | VAF 5/38 reads (13%) | catalogued as COSV99733764; called by muse, mutect2, varscan2
- MLH3 | c.4119C>T p.S1373= (on ENST00000355774 / NM_001040108.2; = p.S1349= on NM_014381.3) | Silent (SNP) | VAF 18/49 reads (37%) | catalogued as COSV53159832; called by muse, mutect2, varscan2
- MYH2 | c.2454C>T p.F818= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as COSV99819125; called by muse, mutect2, varscan2
- NDUFAF5 | c.612G>A p.A204= | Silent (SNP) | VAF 15/77 reads (19%) | catalogued as rs147579272; ClinVar: likely benign; called by muse, mutect2, varscan2
- NLRP9 | c.2245T>C p.L749= | Silent (SNP) | VAF 11/76 reads (14%) | catalogued as COSV60464429; called by muse, mutect2, varscan2
- NUTM1 | c.477G>A p.P159= | Silent (SNP) | VAF 7/37 reads (19%) | catalogued as rs768665655, COSV61546295; called by muse, mutect2, varscan2
- OR10X1 | c.492T>G p.A164= | Silent (SNP) | VAF 10/41 reads (24%) | catalogued as COSV63767018, COSV63768118; called by muse, mutect2, varscan2
- PCDH17 | c.3214T>C p.L1072= | Silent (SNP) | VAF 14/66 reads (21%) | catalogued as rs1320589035, COSV64971461, COSV64971783, COSV64972529; called by muse, mutect2, varscan2
- PCDHA11 | c.2250G>A p.S750= | Silent (SNP) | VAF 19/31 reads (61%) | catalogued as rs374659815; called by muse, mutect2, varscan2
- PLK2 | c.21C>A p.I7= | Silent (SNP) | VAF 5/34 reads (15%) | catalogued as COSV99955722; called by muse, mutect2, varscan2
- PSG7 | c.318C>G p.S106= | Silent (SNP) | VAF 158/562 reads (28%) | catalogued as COSV101343175; called by muse, mutect2, varscan2
- RALGAPA1 | c.3954G>A p.L1318= | Silent (SNP) | VAF 44/148 reads (30%) | catalogued as COSV99352911; called by muse, mutect2, varscan2
- RINT1 | c.1689A>G p.Q563= | Silent (SNP) | VAF 12/74 reads (16%) | catalogued as COSV99994168; called by muse, mutect2, varscan2
- SACS | c.9138C>G p.T3046= | Silent (SNP) | VAF 62/137 reads (45%) | catalogued as COSV101207136; called by muse, mutect2, varscan2
- SEPTIN3 | c.378C>T p.T126= | Silent (SNP) | VAF 11/50 reads (22%) | catalogued as COSV99351881; called by muse, mutect2, varscan2
- SH3RF3 | c.1284C>T p.C428= | Silent (SNP) | VAF 7/27 reads (26%) | catalogued as rs774206163, COSV100512221, COSV58679613; called by muse, mutect2, varscan2
- SLC39A11 | c.267G>A p.A89= | Silent (SNP) | VAF 10/57 reads (18%) | catalogued as rs771535234, COSV99722085; called by muse, mutect2, varscan2
- TFAP2D | c.1167G>A p.P389= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs149503577; called by muse, mutect2, varscan2
- TOX2 | c.1311G>A p.P437= (on ENST00000358131 / NM_001098798.2; = p.P413= on NM_032883.3) | Silent (SNP) | VAF 13/82 reads (16%) | catalogued as rs764418226, COSV100363243; called by muse, mutect2, varscan2
- TTC39B | c.774C>T p.I258= | Silent (SNP) | VAF 12/43 reads (28%) | catalogued as rs530156692, COSV99893981; called by muse, mutect2, varscan2
- TUBB6 | c.225C>T p.S75= | Silent (SNP) | VAF 9/24 reads (38%) | catalogued as rs1267098226, COSV58354476; called by muse, mutect2, varscan2
- USP29 | c.270A>G p.R90= | Silent (SNP) | VAF 9/81 reads (11%) | catalogued as COSV99571633; called by muse, mutect2, varscan2
- ZCCHC24 | c.423A>T p.G141= | Silent (SNP) | VAF 12/30 reads (40%) | catalogued as rs1217442915, COSV100959265; called by muse, mutect2, varscan2
- ZFP3 | c.378A>G p.L126= | Silent (SNP) | VAF 26/77 reads (34%) | catalogued as rs1286891107, COSV100603661; called by muse, mutect2, varscan2
- ZGRF1 | c.2727C>A p.S909= | Silent (SNP) | VAF 19/76 reads (25%) | catalogued as COSV100005278; called by muse, mutect2, varscan2
- ZNF577 | c.975T>G p.P325= | Silent (SNP) | VAF 51/114 reads (45%) | catalogued as COSV100030683; called by muse, mutect2, varscan2
- ZNF813 | c.975A>G p.K325= | Silent (SNP) | VAF 37/260 reads (14%) | catalogued as COSV101124664; called by muse, mutect2, varscan2
- HTR2C | c.-79-11621G>A | Intron (SNP) | VAF 25/40 reads (63%) | catalogued as COSV99347905; called by muse, mutect2, varscan2
- KLK8 | c.71-28C>T | Intron (SNP) | VAF 28/102 reads (27%) | catalogued as rs764327775, COSV99143865; called by muse, mutect2, varscan2
- NTRK3 | c.1586-38653A>C | Intron (SNP) | VAF 28/131 reads (21%) | catalogued as rs1190819961, COSV100445098, COSV58122108; called by muse, mutect2, varscan2
